Somatic mutation profile of tumor specimen TCGA-85-8582-01A (aliquot TCGA-85-8582-01A-21D-2395-08) from TCGA case TCGA-85-8582, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 49.7 years (18,168 days).
Specimen TCGA-85-8582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2200c600-f464-438d-8d56-4c38771df432.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8582-10A (Blood Derived Normal), aliquot TCGA-85-8582-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/381cc3d3-808d-4b45-a160-6c741eefa1f0

The open-access MAF lists 350 somatic variants for this specimen: 278 protein-altering or splice-affecting, 68 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 68, Nonsense Mutation 16, Frame Shift Del 7, Splice Site 6, Frame Shift Ins 2, Intron 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.372C>G p.N124K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV100588556, COSV59383658; called by muse, mutect2, varscan2
- ABCA5 | c.547G>C p.A183P | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101201062; called by muse, mutect2, varscan2
- ABCB10 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100747886; called by muse, mutect2, varscan2
- ACTN2 | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100856666; called by muse, mutect2
- ADAM2 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV99697038; called by muse, mutect2, varscan2
- ADAMTS2 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99201169; called by muse, mutect2, varscan2
- AHCTF1 | c.5048A>G p.D1683G (on ENST00000366508; = p.D1657G on NM_015446.5) | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100403383; called by muse, mutect2, varscan2
- AHSG | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99889926; called by muse, mutect2
- AMDHD2 | c.949G>C p.G317R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV99565715; called by muse, mutect2, varscan2
- ANKRD30A | c.1648C>A p.P550T (on ENST00000611781; = p.P494T on NM_052997.2) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as COSV100653171, COSV64609766; called by muse, mutect2, varscan2
- ANKZF1 | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99850389; called by muse, varscan2
- AP2A1 | c.1731G>T p.Q577H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100756200; called by muse, mutect2, varscan2
- APBA2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101382069; called by muse, mutect2, varscan2
- APLP1 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV99383754; called by muse, mutect2, varscan2
- ASCC3 | c.6580G>T p.D2194Y | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV100976325, COSV64978149; called by muse, mutect2, varscan2
- ASCL4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs759886915, COSV60816645; called by muse, mutect2, varscan2
- ASMTL | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV101187724; called by muse, mutect2, varscan2
- ATF3 | c.494A>T p.D165V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99674462; called by muse, mutect2, varscan2
- ATF7IP2 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV100202562; called by muse, mutect2, varscan2
- BCL9L | c.4368G>T p.Q1456H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99418937; called by muse, mutect2
- BIVM-ERCC5 | c.4094A>G p.D1365G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100863690; called by muse, varscan2
- BOD1L1 | c.7162G>T p.G2388W | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99238884; called by muse, mutect2
- BRINP3 | c.1878C>A p.H626Q | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100818566; called by muse, mutect2
- C20orf85 | c.56A>T p.Q19L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100959418; called by muse, mutect2, varscan2
- C6orf118 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100024278; called by muse, mutect2, varscan2
- CA10 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.2); catalogued as COSV53336161; called by muse, mutect2
- CACNA1B | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1484069722, COSV53122885, COSV99496147; called by muse, mutect2, varscan2
- CACNA1D | c.5821C>T p.P1941S (on ENST00000350061 / NM_001128840.3; = p.P1961S on NM_000720.4) | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.277); catalogued as COSV55447359; called by muse, mutect2
- CADM2 | c.1166G>T p.G389V (on ENST00000407528 / NM_001167674.2; = p.G391V on NM_153184.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101053670; called by muse, mutect2
- CAMKV | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.817); catalogued as COSV56558057, COSV99615312; called by muse, mutect2
- CCNL2 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100784953; called by muse, mutect2, varscan2
- CD1D | c.294C>G p.D98E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100939568, COSV63808401; called by muse, mutect2
- CDH11 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99217735; called by muse, mutect2, varscan2
- CDH12 | c.1760T>C p.I587T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV101201965; called by muse, mutect2
- CDH4 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100848626; called by muse, mutect2, varscan2
- CEP97 | c.1921A>T p.T641S | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100511613; called by muse, mutect2, varscan2
- CETN1 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100511262; called by muse, mutect2, varscan2
- CNGA4 | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV101171773; called by muse, mutect2
- COL21A1 | c.2600G>T p.G867V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778041; called by muse, mutect2, varscan2
- CPA5 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.666); catalogued as rs139419630, COSV100812262; called by muse, mutect2, varscan2
- CPB1 | c.754A>G p.R252G | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294162; called by muse, mutect2, varscan2
- CPNE8 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100504119; called by muse, mutect2, varscan2
- CPS1 | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51802782, COSV99242540; called by muse, mutect2, varscan2
- CR1L | c.973A>G p.R325G | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV99687003; called by muse, mutect2
- CRACR2A | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99364791; called by muse, mutect2, varscan2
- CSDE1 | c.32A>G p.N11S | Missense Mutation (SNP) | VAF 56/518 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs777883903, COSV99794469; called by muse, mutect2
- CSF3 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99842349; called by muse, mutect2, varscan2
- CSHL1 | c.494T>A p.L165Q (on ENST00000309894 / NM_022581.3; = p.L71Q on NM_001318.4) | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200267741, COSV99367865; called by muse, mutect2, varscan2
- CSMD3 | c.9950G>T p.C3317F (on ENST00000297405 / NM_001363185.1; = p.C3148F on NM_052900.3) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52303636, COSV99829433; called by muse, mutect2, varscan2
- CSMD3 | c.4565G>C p.S1522T (on ENST00000297405 / NM_001363185.1; = p.S1418T on NM_052900.3) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.974); catalogued as COSV52330099, COSV99829437; called by muse, mutect2
- CYP4F2 | c.1471G>T p.V491F | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV55618439, COSV99685840; called by muse, mutect2, varscan2
- DCAF8L1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV101491371, COSV101491427; called by muse, mutect2, varscan2
- DDHD1 | c.1849G>T p.E617* (on ENST00000323669; = p.E814* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100079281, COSV100080255; called by muse, mutect2
- DENND2C | c.2054G>T p.C685F (on ENST00000393274 / NM_001256404.2; = p.C628F on NM_198459.4) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101283907; called by muse, mutect2, varscan2
- DEPTOR | c.1224G>C p.E408D | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99638214; called by muse, mutect2, varscan2
- DLGAP3 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.046); catalogued as rs747689409, COSV52395602; called by muse, mutect2, varscan2
- DNAH5 | c.7994A>G p.N2665S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774224537, COSV99447180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.2771C>T p.T924I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs367951191, COSV99447183; called by muse, mutect2, varscan2
- DNAI4 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1160094014, COSV100590884; called by muse, mutect2
- DUXA | c.439-1G>T p.X147_splice | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as COSV73729636, COSV73729899; called by muse, mutect2
- ELAVL4 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV100836641, COSV63915128, COSV63918303; called by muse, mutect2, varscan2
- ENOSF1 | c.705C>A p.Y235* (on ENST00000340116 / NM_001354066.2; = p.Y187* on NM_017512.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/97 reads (9%) | catalogued as COSV51892217, COSV99201005; called by muse, mutect2, varscan2
- EPHX2 | c.933A>C p.E311D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV100994529; called by muse, mutect2, varscan2
- ERBIN | c.3511A>G p.K1171E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs751121524, COSV99396369; called by muse, mutect2, varscan2
- ERICH3 | c.4451G>T p.R1484M | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV100443840; called by muse, mutect2, varscan2
- ETFB | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164273, COSV58536345; called by muse, varscan2
- FAM135B | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs779793997, COSV50521953, COSV99356912; called by muse, mutect2
- FEZF1 | c.480G>T p.L160F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1048562563, COSV100484451; called by muse, mutect2
- FGA | c.2257C>A p.L753I | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100120218; called by muse, mutect2, varscan2
- FGB | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM117841, COSV100122375; called by muse, mutect2
- FOLH1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs748829971, COSV99922943; called by muse, mutect2, varscan2
- FRMPD2 | c.3281T>A p.V1094E | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100563679; called by muse, mutect2, varscan2
- GABRA2 | c.937A>T p.M313L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV100734028; called by muse, mutect2, varscan2
- GABRE | c.1013C>G p.T338R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100944244; called by muse, mutect2, varscan2
- GPR55 | c.914C>A p.S305Y | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV101235782; called by muse, mutect2, varscan2
- GRIA2 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.984); catalogued as COSV99643670; called by muse, mutect2, varscan2
- GTF2A1 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993355; called by muse, mutect2, varscan2
- GUCY1B1 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100025432; called by muse, mutect2, varscan2
- H2BC3 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as rs747391525, COSV100778267; called by muse, mutect2
- HERC2 | c.3941G>T p.G1314V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99872080; called by muse, mutect2, varscan2
- HERPUD2 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV100257869; called by muse, mutect2, varscan2
- HLX | c.719T>A p.L240* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | catalogued as COSV100854491; called by muse, mutect2, varscan2
- HNF4A | c.1130-1G>T p.X377_splice | Splice Site (SNP) | VAF 14/103 reads (14%) | catalogued as COSV100291231; called by muse, mutect2, varscan2
- HOXB8 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV99493945; called by muse, mutect2
- HS3ST4 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV100500625; called by muse, mutect2, varscan2
- HSPA8 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99914294; called by muse, mutect2, varscan2
- HTR5A | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.231); catalogued as rs1387759460, COSV55281358, COSV55283648; called by muse, mutect2, varscan2
- IGKV1D-33 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101134046; called by muse, varscan2
- INHA | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV99216510; called by muse, mutect2
- INO80 | c.4268G>A p.G1423E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as COSV100731680, COSV62739266; called by muse, mutect2, varscan2
- ITM2A | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV100964430; called by muse, mutect2, varscan2
- KCNA3 | c.566T>G p.L189R | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100871225; called by muse, mutect2, varscan2
- KCNA4 | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068745; called by muse, mutect2, varscan2
- KCNA7 | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99671872; called by muse, mutect2
- KCNH2 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV100059554, COSV51140833; called by muse, mutect2, varscan2
- KCNQ1 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99326251; called by muse, mutect2, varscan2
- KCNT2 | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV99652521; called by muse, mutect2, varscan2
- KIF14 | c.3300C>G p.I1100M | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100950726; called by muse, mutect2
- KIR3DL2 | c.1071C>A p.F357L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as COSV54396335, COSV99551897; called by muse, mutect2
- KLF5 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV66614445, COSV66614565; called by muse, mutect2, varscan2
- LAS1L | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100408511; called by muse, mutect2, varscan2
- LEPR | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as COSV100756452; called by muse, mutect2, varscan2
- LRFN5 | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99983074; called by muse, mutect2
- LRRC8C | c.971T>G p.L324R | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100968165; called by muse, mutect2, varscan2
- LRRTM4 | c.163A>T p.I55F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV101297478; called by muse, mutect2
- LY75 | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV55112789, COSV99716211; called by muse, mutect2, varscan2
- MAB21L3 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV101046331; called by muse, mutect2, varscan2
- MAGEB6 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as COSV66872625; called by muse, mutect2, varscan2
- MAML3 | c.2909G>C p.G970A | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV101558379, COSV101558563; called by muse, mutect2
- MAPK1 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV99307881; called by muse, mutect2, varscan2
- MAPK8IP3 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.906); catalogued as rs1283951031, COSV99167797; called by muse, mutect2
- MARCHF4 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764897349, COSV99814184; called by muse, mutect2
- MBD5 | c.1698G>T p.L566F | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV101290003; called by muse, mutect2, varscan2
- MED12 | c.2396T>G p.L799R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100376934; called by muse, mutect2, varscan2
- MFSD14A | c.1186T>C p.F396L | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99790711; called by muse, mutect2, varscan2
- MICU2 | c.1047G>T p.E349D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV101212422; called by muse, mutect2, varscan2
- MMP16 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54182834, COSV99686948; called by muse, mutect2, varscan2
- MRTFB | c.2324C>T p.S775L (on ENST00000571589 / NM_001365412.2; = p.S725L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100370853; called by muse, mutect2, varscan2
- MYH13 | c.1569C>G p.I523M | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99353090; called by muse, mutect2, varscan2
- MYH2 | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV99819676; called by muse, mutect2, varscan2
- MYOC | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV99231385; called by muse, mutect2
- MYOM3 | c.3566C>A p.A1189E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100141620, COSV58391697; called by muse, mutect2, varscan2
- NECTIN2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV99374860; called by muse, mutect2
- NFRKB | c.3169G>T p.A1057S (on ENST00000446488 / NM_001143835.2; = p.A1082S on NM_006165.3) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.088); catalogued as COSV58759258; called by muse, mutect2, varscan2
- NGLY1 | c.1004-1G>T p.X335_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99770313; called by muse, mutect2, varscan2
- NID2 | c.236C>G p.T79S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV99355748, COSV99356199; called by muse, mutect2
- NPBWR2 | c.584C>A p.P195Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.167); catalogued as COSV100871097; called by muse, mutect2, varscan2
- NUTM2F | c.260C>A p.T87K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53558580, COSV99479990; called by muse, mutect2, varscan2
- NXF3 | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101221908; called by muse, mutect2, varscan2
- OPRPN | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.378); catalogued as COSV68192848; called by muse, mutect2
- OR2AT4 | c.770A>T p.Y257F | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100532309; called by muse, mutect2
- OR2L2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 30/383 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as COSV100823335; called by muse, mutect2
- OR2M7 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 37/430 reads (9%) | catalogued as COSV100522472; called by muse, mutect2
- OR2T1 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 10/172 reads (6%) | catalogued as COSV100822278; called by muse, mutect2
- OR2T2 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100737621; called by muse, mutect2, varscan2
- OR2T4 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100822426, COSV63545270; called by muse, mutect2
- OR4A5 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100157012, COSV100157146, COSV100157410; called by muse, mutect2, varscan2
- OR4D6 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs149091895, COSV100271632, COSV55658989; called by muse, mutect2, varscan2
- OR52B4 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV101281580; called by muse, mutect2, varscan2
- OR5D16 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101003892; called by muse, mutect2, varscan2
- OR5D18 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 37/333 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100450613; called by muse, mutect2, varscan2
- OR5D18 | c.251T>A p.V84E | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1035988441, COSV100450614; called by muse, mutect2, varscan2
- OR5I1 | c.320G>C p.C107S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV100041305; called by muse, mutect2, varscan2
- OR5L1 | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs372180673; called by muse, mutect2, varscan2
- OR6F1 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV100129049; called by muse, mutect2
- OR8H3 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs767817191, COSV57911553; called by muse, mutect2, varscan2
- OR8K5 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV100537178, COSV57889361; called by muse, mutect2, varscan2
- OTX2 | c.601T>A p.C201S (on ENST00000408990 / NM_172337.3; = p.C209S on NM_021728.4) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100257833; called by muse, mutect2, varscan2
- P2RY8 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183969, COSV67177749; called by muse, mutect2, varscan2
- PACSIN1 | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99762951; called by muse, mutect2, varscan2
- PADI2 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100970893; called by muse, mutect2
- PCDH17 | c.761A>T p.E254V | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100931521; called by muse, mutect2, varscan2
- PCDHA3 | c.1458G>C p.E486D | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV100793266, COSV63541062; called by muse, mutect2, varscan2
- PCDHB7 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.168); catalogued as COSV99176481; called by muse, mutect2, varscan2
- PDE11A | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs752822096, COSV53690964; called by muse, mutect2
- PELI1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100735096; called by muse, mutect2, varscan2
- PHB | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.483); catalogued as COSV100303136; called by muse, mutect2, varscan2
- PHF19 | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100876271; called by muse, mutect2, varscan2
- PHF20L1 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99620762, COSV99621215; called by muse, mutect2, varscan2
- PHKG1 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99818110; called by muse, mutect2
- PIK3CB | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV100005376, COSV56690316; called by muse, mutect2, varscan2
- PKD1L2 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1395341094, COSV61411402; called by muse, mutect2
- PKHD1 | c.6789A>T p.L2263F | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.522); catalogued as COSV100582141; called by muse, mutect2
- PNLIPRP1 | c.461T>A p.L154H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724306; called by muse, mutect2, varscan2
- PRKG2 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52324317; called by muse, mutect2
- PRODH2 | c.805G>T p.E269* (on ENST00000301175; = p.E193* on NM_021232.2 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99995239; called by muse, mutect2, varscan2
- PRR27 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | catalogued as COSV100748770; called by muse, mutect2, varscan2
- PTEN | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071949, COSV64296353, COSV64297833; called by muse, mutect2, varscan2
- PTPRD | c.5288C>G p.S1763C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100644015, COSV61965305; called by muse, mutect2, varscan2
- RAB3C | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51434534; called by muse, mutect2, varscan2
- RABGAP1L | c.2312G>T p.R771I | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV99268917; called by muse, mutect2
- RANBP3 | c.1621G>A p.D541N (on ENST00000340578 / NM_007322.3; = p.D536N on NM_003624.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs776798051, COSV50380350; called by mutect2, varscan2
- RAX | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753064502, COSV99900212; called by muse, mutect2, varscan2
- RBPJ | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV100623571; called by muse, mutect2, varscan2
- RFWD3 | c.1271G>T p.C424F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV100736200; called by muse, mutect2, varscan2
- RNF2 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV100835693; called by muse, mutect2, varscan2
- RTTN | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99731629; called by muse, mutect2, varscan2
- RUBCNL | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV100528920; called by muse, mutect2, varscan2
- RYR1 | c.2550C>A p.F850L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100615193, COSV62101418; called by muse, mutect2
- RYR2 | c.4590C>A p.Y1530* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100769004; called by muse, mutect2
- RYR2 | c.5010C>A p.H1670Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV100769005, COSV63708384; called by muse, mutect2, varscan2
- SCN4A | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV101438386; called by muse, mutect2
- SERPINE3 | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100246960; called by mutect2, varscan2
- SETD1A | c.1138A>C p.T380P | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99352674; called by muse, mutect2, varscan2
- SFSWAP | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55526413, COSV99905905; called by muse, mutect2, varscan2
- SGIP1 | c.1023C>A p.D341E | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99390962; called by muse, mutect2
- SGSM1 | c.102T>G p.F34L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV101240574; called by muse, mutect2, varscan2
- SIGLECL1 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100323866; called by muse, mutect2, varscan2
- SKOR1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 6/108 reads (6%) | catalogued as COSV100408246; called by muse, mutect2
- SLC17A6 | c.1417C>A p.R473S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV54141742, COSV99581096; called by muse, mutect2, varscan2
- SLC17A8 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs149971292; called by muse, mutect2, varscan2
- SLC24A1 | c.1848G>T p.R616S | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV99978140; called by muse, mutect2
- SLC25A15 | c.275T>A p.V92E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100090799; called by muse, mutect2
- SLC32A1 | c.1274A>T p.D425V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV99461986; called by muse, mutect2, varscan2
- SLC4A10 | c.1315G>C p.E439Q (on ENST00000446997 / NM_001354461.2; = p.E409Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99763107; called by muse, mutect2, varscan2
- SLC5A12 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV54820572, COSV54824746; called by muse, mutect2, varscan2
- SLC5A8 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV101610527; called by mutect2, varscan2
- SLC9A2 | c.1515+2T>A p.X505_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV52138248; called by muse, mutect2, varscan2
- SLCO2B1 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV56935228, COSV99214439; called by muse, mutect2, varscan2
- SLCO2B1 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV99214442; called by muse, mutect2, varscan2
- SLIT3 | c.3686+1G>T p.X1229_splice | Splice Site (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100266194; called by muse, mutect2, varscan2
- SLIT3 | c.3686G>T p.S1229I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100266195; called by muse, mutect2, varscan2
- SLITRK2 | c.1642A>T p.N548Y | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100157517; called by muse, mutect2, varscan2
- SMPD4 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV100302295; called by muse, mutect2, varscan2
- SNRNP200 | c.2359G>T p.A787S | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM149176, COSV100107379; called by muse, mutect2, varscan2
- SORCS1 | c.2879G>T p.G960V | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99544687; called by muse, mutect2, varscan2
- SPATA1 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99759663; called by muse, mutect2, varscan2
- SPOCK3 | c.199-1G>T p.X67_splice | Splice Site (SNP) | VAF 9/80 reads (11%) | catalogued as COSV62731271; called by muse, mutect2, varscan2
- SPTA1 | c.2106G>A p.W702* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100934645; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | PolyPhen benign (0.031); catalogued as COSV100082343; called by muse, mutect2, varscan2
- STAB1 | c.2282A>C p.D761A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100401436; called by muse, mutect2, varscan2
- STRC | c.4457C>G p.S1486* | Nonsense Mutation (SNP) | VAF 12/109 reads (11%) | catalogued as rs1170596050, COSV100294505; called by muse, mutect2, varscan2
- SULF1 | c.1604C>G p.P535R | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99482588; called by muse, mutect2
- SYNE1 | c.4185G>T p.Q1395H (on ENST00000367255 / NM_182961.4; = p.Q1402H on NM_033071.3) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV54919155; called by muse, mutect2, varscan2
- TAGAP | c.1869G>T p.M623I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV100487338; called by muse, mutect2, varscan2
- TBC1D9 | c.3506G>T p.S1169I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV101464299; called by muse, mutect2
- TCF23 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV56078549, COSV99940305; called by muse, mutect2
- TDP1 | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100187696; called by muse, mutect2
- TERF2IP | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.038); catalogued as rs1326102774, CM150703; called by mutect2, varscan2
- TEX11 | c.1007A>G p.D336G (on ENST00000344304; = p.D321G on NM_031276.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1476208283, COSV100721477; called by muse, mutect2, varscan2
- TF | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1447255392, COSV99395571; called by muse, mutect2, varscan2
- THSD7A | c.1774T>A p.C592S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448596; called by muse, mutect2, varscan2
- THSD7B | c.2423G>C p.C808S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99743036, COSV99747229; called by muse, mutect2, varscan2
- TKTL2 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV54918476, COSV54919858, COSV99761244; called by muse, mutect2
- TLN2 | c.4777G>T p.E1593* | Nonsense Mutation (SNP) | VAF 29/175 reads (17%) | catalogued as COSV100168478, COSV60891110; called by muse, mutect2, varscan2
- TNN | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV99511508, COSV99513040; called by muse, mutect2, varscan2
- TPCN1 | c.106A>T p.S36C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as COSV100136553; called by muse, mutect2, varscan2
- TRIM26 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs752818823, COSV101359421; called by muse, mutect2, varscan2
- TRUB1 | c.942G>T p.E314D | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV100076030; called by muse, mutect2, varscan2
- TSGA10 | c.22A>T p.S8C | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100747477, COSV61823714; called by muse, mutect2
- TSHZ2 | c.2905C>G p.Q969E | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV61591513; called by muse, mutect2, varscan2
- TTC37 | c.2269G>T p.E757* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100706470; called by muse, mutect2, varscan2
- TTF2 | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV101037354; called by muse, mutect2, varscan2
- TTLL9 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.178); catalogued as COSV100206507; called by muse, mutect2, varscan2
- TTN | c.37099C>A p.P12367T (on ENST00000591111; = p.P4943T on NM_003319.4) | Missense Mutation (SNP) | VAF 7/101 reads (7%) | PolyPhen probably damaging (0.999); catalogued as COSV100602012; called by muse, mutect2
- TTN | c.12481T>A p.C4161S (on ENST00000591111; = p.C4115S on NM_003319.4) | Missense Mutation (SNP) | VAF 25/233 reads (11%) | catalogued as rs1330751364, COSV100602017; called by muse, mutect2, varscan2
- TUBA3E | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV99919737; called by muse, mutect2, varscan2
- TUBB6 | c.834C>G p.S278R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as COSV99301679; called by muse, mutect2
- TYK2 | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1303144673, COSV53384829; called by muse, mutect2, varscan2
- UBC | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.375); catalogued as COSV100298876; called by muse, varscan2
- USH2A | c.5475G>T p.E1825D | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100231900; called by muse, mutect2, varscan2
- USP19 | c.1021C>A p.H341N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.018); catalogued as COSV100025970; called by muse, mutect2, varscan2
- USP35 | c.1542C>G p.S514R | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV101489062; called by muse, mutect2
- USP6 | c.1934A>T p.K645M | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs773774641, COSV100003524; called by muse, mutect2, varscan2
- VANGL2 | c.545G>C p.R182P | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100925549; called by muse, mutect2
- WASHC2A | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV99254562; called by muse, mutect2, varscan2
- WASHC2C | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100313862; called by muse, mutect2
- XCL2 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100892246; called by muse, mutect2, varscan2
- ZBED9 | c.1161T>A p.D387E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV101509178; called by muse, mutect2, varscan2
- ZFHX4 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as rs1012994742, COSV99260059; called by muse, mutect2, varscan2
- ZFP14 | c.1242C>G p.H414Q | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99525083; called by muse, mutect2, varscan2
- ZNF17 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV56921363; called by muse, mutect2, varscan2
- ZNF208 | c.3180A>T p.E1060D | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.751); catalogued as COSV68107873; called by muse, mutect2, varscan2
- ZNF215 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV53493520, COSV99549410; called by muse, mutect2, varscan2
- ZNF382 | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53087067, COSV99497611; called by muse, mutect2, varscan2
- ZNF418 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.838); catalogued as COSV101268911; called by muse, mutect2, varscan2
- ZNF462 | c.6508C>A p.R2170S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99471211; called by muse, mutect2, varscan2
- ZNF665 | c.1802A>T p.N601I (on ENST00000600412; = p.N666I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV101128125; called by muse, mutect2
- ZNF7 | c.1951A>G p.I651V | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV100295745; called by muse, mutect2, varscan2
- ZSCAN5B | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1456500013, COSV100627909; called by muse, mutect2, varscan2
- CCL28 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.04); called by muse, mutect2
- COL22A1 | c.4111C>A p.P1371T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.129); called by muse, mutect2
- GPR142 | c.1315del p.A439Hfs*12 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel
- IGHA1 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- LILRA6 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- MAGEB6B | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- NDRG3 | c.875del p.G292Dfs*5 (on ENST00000349004 / NM_032013.4; = p.G280Dfs*5 on NM_022477.4) | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- NEK7 | c.520dup p.V174Gfs*37 | Frame Shift Ins (INS) | VAF 15/97 reads (15%) | called by mutect2, pindel, varscan2
- NRSN1 | c.263C>G p.P88R | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.106); called by muse, mutect2
- OPRK1 | c.119del p.G40Afs*29 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, varscan2
- OR2G6 | c.87del p.I30Sfs*8 | Frame Shift Del (DEL) | VAF 27/200 reads (14%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SPPL3 | c.102del p.R34Sfs*52 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel
- TRBV24-1 | c.244G>T p.G82* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- TRPC4 | c.2115dup p.Y706Ifs*18 (on ENST00000379705 / NM_016179.4; = p.Y711Ifs*18 on NM_003306.3) | Frame Shift Ins (INS) | VAF 16/176 reads (9%) | called by mutect2, pindel
- TRPM1 | c.4654del p.S1552Vfs*9 | Frame Shift Del (DEL) | VAF 45/233 reads (19%) | called by mutect2, pindel, varscan2
- ZNF354A | c.404del p.K135Sfs*10 | Frame Shift Del (DEL) | VAF 12/136 reads (9%) | called by mutect2, pindel
- AACS | c.792C>A p.A264= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99907872; called by muse, mutect2, varscan2
- ABCA9 | c.750A>G p.Q250= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs1247909445, COSV100382854; called by muse, mutect2, varscan2
- CARD17 | c.258G>T p.T86= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV100995186, COSV100995266; called by muse, mutect2, varscan2
- CCDC74B | c.966G>A p.T322= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs755279496, COSV100134202; called by muse, mutect2, varscan2
- CCT8L2 | c.25C>T p.L9= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100742626; called by muse, mutect2, varscan2
- CEP41 | c.522G>T p.L174= | Silent (SNP) | VAF 22/245 reads (9%) | catalogued as COSV99782652; called by muse, mutect2
- COL7A1 | c.6276C>T p.P2092= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100095507; called by muse, mutect2, varscan2
- DNAH8 | c.1809C>T p.P603= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100544060; called by muse, mutect2, varscan2
- ELSPBP1 | c.39C>A p.T13= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs763950451, COSV100353547; called by muse, mutect2, varscan2
- FAAH | c.1206G>T p.G402= | Silent (SNP) | VAF 38/408 reads (9%) | catalogued as COSV99679988; called by muse, mutect2
- FPR1 | c.438C>A p.I146= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100493985, COSV59052729; called by muse, mutect2, varscan2
- GABRA2 | c.936C>A p.A312= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV100734030; called by muse, mutect2, varscan2
- GHR | c.1716T>G p.L572= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100050225; called by muse, mutect2
- GPR108 | c.1044G>A p.L348= (on ENST00000264080 / NM_001080452.1; = p.L106= on NM_020171.2) | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV51184444, COSV51186880; called by muse, mutect2
- GRIA2 | c.180C>A p.P60= | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- GRIN3A | c.2901C>A p.S967= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100701424; called by muse, mutect2
- GTF3C1 | c.5790G>A p.E1930= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as COSV100649153; called by muse, mutect2, varscan2
- HOXD1 | c.865C>A p.R289= | Silent (SNP) | VAF 15/227 reads (7%) | catalogued as COSV100514127, COSV100514270; called by muse, mutect2
- IFNLR1 | c.975C>T p.D325= | Silent (SNP) | VAF 32/267 reads (12%) | catalogued as rs368532574; called by muse, mutect2, varscan2
- ITGA4 | c.2364G>C p.V788= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV101223216; called by muse, mutect2, varscan2
- ITPKC | c.1554C>T p.D518= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs746367995, COSV99648559; called by muse, mutect2, varscan2
- KCNH8 | c.2388G>A p.L796= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV100109152; called by muse, mutect2, varscan2
- KIFC3 | c.2121C>T p.V707= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs111598367; called by muse, mutect2, varscan2
- KLHL1 | c.1005C>T p.S335= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs762176704, COSV100917123; called by mutect2, varscan2
- LGALS1 | c.366A>T p.A122= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV99313749; called by muse, mutect2, varscan2
- LINGO2 | c.1545T>C p.P515= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV100430378; called by muse, mutect2, varscan2
- MAB21L2 | c.324G>A p.R108= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs200271959, COSV100462012, COSV100462266; called by muse, mutect2, varscan2
- MAPT | c.2457G>A p.T819= (on ENST00000262410 / NM_001377265.1; = p.T427= on NM_005910.5) | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs369954009; ClinVar: likely benign; called by muse, mutect2
- MED12 | c.2397G>C p.L799= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100376937; called by muse, mutect2, varscan2
- MITD1 | c.45A>G p.A15= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV99175548; called by muse, mutect2, varscan2
- MUC16 | c.40062C>A p.V13354= | Silent (SNP) | VAF 19/267 reads (7%) | catalogued as rs1002414847, COSV101109734; called by muse, mutect2
- MUC16 | c.32493C>A p.T10831= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as COSV67459030; called by muse, mutect2, varscan2
- MYCBP2 | c.4749A>G p.K1583= (on ENST00000357337; = p.K1621= on NM_015057.5) | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV100629665; called by muse, mutect2, varscan2
- NOL4L | c.222C>A p.A74= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100675592; called by muse, mutect2, varscan2
- OR4N2 | c.240G>T p.R80= | Silent (SNP) | VAF 66/319 reads (21%) | catalogued as COSV60056106; called by muse, mutect2, varscan2
- OR5B2 | c.255A>G p.R85= | Silent (SNP) | VAF 90/244 reads (37%) | catalogued as COSV100222818; called by muse, mutect2, varscan2
- OR5K4 | c.555T>C p.Y185= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs772571681, COSV100721319; called by muse, mutect2, varscan2
- OR6F1 | c.690T>A p.S230= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as COSV100129043; called by muse, mutect2, varscan2
- PAQR7 | c.555C>T p.S185= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV100961645; called by muse, mutect2
- PCDHB12 | c.1452C>A p.A484= | Silent (SNP) | VAF 45/273 reads (16%) | catalogued as COSV99506589; called by muse, mutect2, varscan2
- PCOLCE2 | c.516C>T p.D172= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV99930506; called by muse, mutect2, varscan2
- PDCD6IP | c.612A>T p.T204= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV100218643; called by muse, mutect2, varscan2
- PGK2 | c.369C>T p.R123= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV59165520; called by muse, mutect2, varscan2
- PREX1 | c.585G>T p.P195= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100906133, COSV64250523; called by muse, mutect2, varscan2
- PREX2 | c.3643C>A p.R1215= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs964579317, COSV55794645, COSV99906090; called by muse, mutect2, varscan2
- QTRT2 | c.9G>T p.L3= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99846849; called by muse, mutect2, varscan2
- RIMBP2 | c.579C>A p.P193= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV99898864; called by muse, mutect2, varscan2
- RRBP1 | c.315G>T p.V105= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99853754; called by muse, mutect2, varscan2
- RTF1 | c.1770G>A p.Q590= | Silent (SNP) | VAF 57/272 reads (21%) | catalogued as COSV67478249; called by muse, mutect2, varscan2
- SEMA4B | c.2247G>A p.K749= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- SLAMF6 | c.39C>T p.C13= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100924857; called by muse, mutect2, varscan2
- SLC12A6 | c.1542G>A p.K514= (on ENST00000354181 / NM_001365088.1; = p.K463= on NM_005135.2) | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99271385; called by muse, mutect2, varscan2
- SLC5A8 | c.1689C>A p.S563= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV101610526; called by muse, mutect2, varscan2
- SPPL2C | c.1305C>A p.T435= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100233978; called by muse, mutect2
- STPG2 | c.762G>A p.E254= | Silent (SNP) | VAF 17/194 reads (9%) | catalogued as COSV99758631; called by muse, mutect2
- STYXL2 | c.1386C>T p.H462= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1318279497, COSV99608846; called by muse, mutect2
- SVEP1 | c.10165C>T p.L3389= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV52841306; called by muse, mutect2, varscan2
- TNXB | c.75C>G p.P25= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100926091; called by muse, mutect2, varscan2
- TRBV4-1 | c.297C>A p.A99= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- TRIML1 | c.993G>C p.L331= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs749847543, COSV100205840, COSV60193317; called by muse, varscan2
- TTN | c.82398T>C p.S27466= (on ENST00000591111; = p.S20042= on NM_003319.4) | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV100602009; called by muse, mutect2, varscan2
- TTN | c.22293T>C p.F7431= (on ENST00000591111; = p.F6504= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100602015; called by muse, mutect2, varscan2
- TTN | c.4362A>T p.L1454= (on ENST00000591111; = p.L1408= on NM_003319.4) | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100602019; called by muse, mutect2, varscan2
- VWCE | c.2274C>T p.H758= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs770129790, COSV57114823; called by muse, mutect2, varscan2
- XIRP2 | c.5841A>G p.G1947= (on ENST00000628543; = p.G2122= on NM_152381.6) | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99740611; called by muse, mutect2, varscan2
- ZFHX4 | c.7842G>T p.P2614= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV51457640, COSV99260068; called by muse, mutect2
- ZNF101 | c.435A>G p.Q145= | Silent (SNP) | VAF 13/215 reads (6%) | catalogued as COSV100543503; called by muse, mutect2
- ZNF669 | c.1383G>T p.V461= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100594235; called by muse, mutect2
- CCSER1 | c.2011-35307G>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100389384; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2388A>T | Intron (SNP) | VAF 13/176 reads (7%) | catalogued as COSV100313882; called by muse, mutect2
- ZNF658B | n.2137C>G | RNA (SNP) | VAF 33/372 reads (9%) | called by muse, mutect2, varscan2
- ZNF99 | c.*302del | 3'UTR (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel
